Somatic mutation profile of tumor specimen MP2PRT-PAVUTJ-TMP1-A (aliquot MP2PRT-PAVUTJ-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUTJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,019 days).
Specimen MP2PRT-PAVUTJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81987cae-e140-48db-bf97-71a3b2559e41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUTJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUTJ-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89b42f4d-3cb4-4406-8a7e-8b8ca44ac0fd

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/305 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH1 | c.572G>C p.R191P | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56850403, COSV99875292; called by muse, mutect2
- PTPN11 | c.213T>A p.F71L | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61005635, COSV61011607; called by muse, mutect2
- SLC52A2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 101/652 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs201705744; called by muse, mutect2, varscan2
- ADGRA3 | c.3398A>T p.N1133I | Missense Mutation (SNP) | VAF 128/470 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- EHBP1L1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ODF1 | c.445T>G p.C149G | Missense Mutation (SNP) | VAF 16/553 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.159); called by muse, mutect2
- RFTN1 | c.1530C>T p.G510= | Silent (SNP) | VAF 150/553 reads (27%) | catalogued as rs771592793; called by muse, mutect2, varscan2
